TARGET case TARGET-10-PASIIK — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/370c6615-5ce4-5048-8948-648f5c4f3f4d

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 3 years; Vital status: Dead; Days to death: 168 days.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 3.9 years (1,415 days); Year of diagnosis: 2008; Days to last follow up: 168 days.
   Treatment given: Protocol identifier: AALL0331.

Follow-up (2 entries)
- Days to follow up: 47 days; Days to first event: 47 days; First event: Relapse.
- Days to follow up: 168 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone marrow; Year of follow up: 2009.

Molecular and laboratory tests (laboratory values grouped by visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- TCF3–PBX1 translocation: Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 10.7 ×10³/µL.
- Day 8: Bone Marrow blast count 91%; Minimal Residual Disease (Flow Cytometry) 13.2%.
- Day 15: Bone Marrow blast count 8%.
- Day 29: Bone Marrow blast count 0%; Minimal Residual Disease (Flow Cytometry) 2.4%.
- Day 43: Bone Marrow blast count 82%; Minimal Residual Disease (Flow Cytometry) 84.8%.

Biospecimens (2 samples)
- Sample TARGET-10-PASIIK-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
- Sample TARGET-10-PASIIK-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Discovery_20230727.xlsx:
- Overall Survival Time in Days: 168
- WBC at Diagnosis: 10.67
- CNS Status at Diagnosis: CNS 1
- MRD Day 8: 13.2
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 2.4
- MRD Day 29 Sensitivity: 0.01
- MRD Day 43: 84.8
- Bone Marrow Site of Relapse: Yes
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 91
- BMA Blasts Day 15: 8
- BMA Blasts Day 29: 0
- BMA Blasts Day 43: 82
- Karyotype: 47,XX,+8,t(14;18)(q32;q21)[19]/46,XX[1]
- Down Syndrome: No
- DNA Index: 1.0884
- Cell of Origin: B-Precursor
- ALL Molecular Subtype: None of the above
